CGCI case HTMCP-03-06-02144 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dafcdbd9-18bb-42d5-9b97-7c9feb9c80c4

Demographics
Sex at birth: female; Race: black or african american; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 45.9 years (16,779 days); Year of diagnosis: 2014; Method of diagnosis: Biopsy; AJCC clinical T: T3b; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 718 days (2.0 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 74 days; Days to treatment end: 92 days; Treatment dose: 45; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Brachytherapy, Low Dose; Treatment intent type: Adjuvant; Treatment dose: 3000; Treatment outcome: Complete Response; Treatment anatomic sites: Cervix.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 4500; Treatment outcome: Complete Response; Treatment anatomic sites: Pelvis.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 0; Treatment outcome: Complete Response; Treatment anatomic sites: Lymph Node(s) Paraaortic.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 357 days; Disease response: With Tumor.
- Days to follow up: 718 days (2.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Weight: 59 kg; Height: 157.1 cm; BMI: 23.9; CD4 count: 486; Haart treatment indicator: Yes; HIV viral load: 0; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples)
- Samples HTMCP-03-06-02144-01A, HTMCP-03-06-02144-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02144-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02144-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 7; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 7; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2004; HIV rna load at diagnosis: 0; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
- Follow-up form 1: Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 1, Treatment, Radiation therapy info: Brachytherapy type: LDR; Radiation therapy xrt type: External beam radiation; Radiation therapy dose paraaortic nodes: 0.
- Follow-up form 2: Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 45.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02144-01A-01R-5099:
- % tumour top: 90
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02144-01A-01D-5099:
- % tumour top: 90
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02144-10A-01D-5099:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02144-01B-01S-6335:
- % tumour top: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02144-01B-01E-6335:
- % tumour top: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet03_20191126.xlsx, for sample HTMCP-03-06-02144-01A-02R-5099:
- % tumour top: 90
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet03_20191126.xlsx, for sample HTMCP-03-06-02144-01A-03R-5099:
- % tumour top: 90
- % tumour bottom: 80
